CGCI case BLGSP-71-27-00411 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/504cd2fc-f577-49aa-a7bc-e289b2955490

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 40 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 40.2 years (14,685 days); Year of diagnosis: 2016; Method of diagnosis: Surgical Resection; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 366 days (1.0 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Iliac; Sites of involvement: Bone marrow / Breast, NOS / Small intestine.
   Pathology details: Lymph node involved site: Inguinal.
   Pathology details: Lymph node involved site: Retroperitoneal.
   Pathology details: Lymph node involved site: Iliac, NOS.
   Pathology details: Lymph node involved site: Mediastinal.
   Pathology details: Lymph node involved site: Supraclavicular.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Axillary; Tumor largest dimension diameter: 3.1 cm.
   Pathology details: Lymph node involved site: Cervical, NOS.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: IVAC; Days to treatment start: 11 days; Days to treatment end: 72 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CODOX-M; Days to treatment start: 11 days; Days to treatment end: 72 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Doxorubicin + Etoposide + Ifosfamide + Methotrexate + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 11 days; Days to treatment end: 72 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Recurrent Disease; Regimen or line of therapy: R-GDP; Days to treatment start: 198 days; Days to treatment end: 273 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Dexamethasone + Gemcitabine + Rituximab; Initial disease status: Recurrent Disease; Days to treatment start: 198 days; Days to treatment end: 273 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Initial disease status: Recurrent Disease; Days to treatment start: 323 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Radiation Therapy, NOS, for progressive disease; adjuvant Radiation Therapy, NOS; Surgery, NOS, for progressive disease.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 2.
- Days to follow up: 195 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Specified parts of peritoneum; Days to progression: 195 days.
- Days to follow up: 366 days (1.0 years); Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD30 (IHC): Negative.
- FOXP1 (IHC): Positive.
- IRF4 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- LMO2 (IHC): Negative.
- MYC (FISH): Normal.
- MYC translocation (FISH): Negative.
- Test (IHC): Negative; Specialized molecular test: GCET1.
- Test (IHC): Negative; Specialized molecular test: SOX11.
- Lactate Dehydrogenase 3215 [Blood test normal range upper: 250].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day 0: Weight: 92.2 kg; Height: 185 cm; BMI: 26.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-27-00411-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Prospective.
  Slide BLGSP-71-27-00411-01A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 25; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-27-00411-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 25; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-27-00411-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-27-00411-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen; Days to sample procurement: 276 days; Method of sample procurement: Blood Draw; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2; Extranodal involvment other: internal mammary, ileocecum; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: segmental resection of ileocecum; Lymph nodes examined: No; Bone marrow sample histology: Concordant Histology.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 3215; Immunophenotypic analysis method: Immunohistochemistry; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD10.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: FOX-P1.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: CD30.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: SOX-11.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunophenotypic analysis tested: MUM-1.
- Tests performed, Genetic testing results, Genetic testing result 10: Immunophenotypic analysis tested: GCET-1.
- Tests performed, Genetic testing results, Genetic testing result 11: Immunophenotypic analysis tested: LMO-2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- New tumor event: New tumor event type: Distant Metastasis; New tumor event site other: omentum; New tumor event diagnosis evidence: Biopsy with Histologic Confirmation; New tumor event diagnosis evidence: Convincing Imaging; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: R-CODOX-M/IVAC + IT MTX/ARA-C; Pharma adjuvant cycles count: 6.
- Treatments, Treatment 2: Therapy regimen: Recurrence; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 4.
- Treatments, Treatment 3: Therapy regimen: Recurrence; Treatment type: Stem Cell Transplant; Stem cell transplantation: Allogeneic- unrelated donor.
